Somatic mutation profile of tumor specimen TCGA-VS-A9V5-01A (aliquot TCGA-VS-A9V5-01A-11D-A42O-09) from TCGA case TCGA-VS-A9V5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.9 years (18,577 days).
Specimen TCGA-VS-A9V5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ec666f-e719-49f9-80e5-4aedea33a74d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9V5-10A (Blood Derived Normal), aliquot TCGA-VS-A9V5-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c7130dc-daf5-43f1-81bb-273afcb2f86a

The open-access MAF lists 151 somatic variants for this specimen: 111 protein-altering or splice-affecting, 40 silent.
By variant classification: Missense Mutation 94, Silent 40, Nonsense Mutation 10, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK5 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as rs782813437, COSV100450802; called by muse, mutect2, varscan2
- ALKBH8 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99509277; called by muse, mutect2, varscan2
- ATL1 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100613368; called by muse, mutect2, varscan2
- BAAT | c.276G>C p.L92F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV99408719; called by muse, mutect2, varscan2
- BAHCC1 | c.7345G>A p.E2449K | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782118091, COSV100312154; called by muse, mutect2, varscan2
- C1QA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1162938034, COSV101009573; called by muse, mutect2, varscan2
- C2orf68 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs757496159, COSV100108363; called by muse, mutect2, varscan2
- C5orf34 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV100175328, COSV100175663; called by muse, mutect2, varscan2
- CACNA1F | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100545519; called by muse, mutect2, varscan2
- CAVIN1 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100824630; called by muse, mutect2, varscan2
- CCNT1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99980952; called by muse, mutect2, varscan2
- CIZ1 | c.1808C>G p.S603C | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV99477194; called by muse, mutect2, varscan2
- CLCA4 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1380783153, COSV100991234; called by muse, mutect2, varscan2
- COL1A1 | c.4109G>A p.C1370Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99868437; called by muse, varscan2
- COL20A1 | c.2210C>A p.S737Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV100491720; called by muse, mutect2
- COL24A1 | c.4849A>G p.I1617V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs767547615, COSV65306076; called by muse, mutect2, varscan2
- CPSF1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs149933897, COSV100574807; called by muse, mutect2, varscan2
- CTNND2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1223300190, COSV100481720; called by muse, mutect2, varscan2
- CUL5 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV101263774; called by muse, mutect2, varscan2
- CUL9 | c.4271G>A p.R1424H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs759503050, COSV52729851; called by muse, varscan2
- CXCR3 | c.860C>G p.A287G | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV101031756; called by muse, mutect2, varscan2
- CYP4V2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV101115011; called by muse, mutect2, varscan2
- DHX32 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs981974319, COSV99502041; called by muse, mutect2, varscan2
- DMGDH | c.1227A>T p.K409N | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV99669651; called by muse, mutect2, varscan2
- DNAH8 | c.10629A>C p.K3543N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100547476, COSV59473422; called by muse, mutect2, varscan2
- DNAJC13 | c.5646G>T p.M1882I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99608379; called by muse, mutect2, varscan2
- DNAJC27 | c.822G>C p.*274Yext*18 | Nonstop Mutation (SNP) | VAF 38/134 reads (28%) | catalogued as rs1029754206, COSV99266487, COSV99266811; called by muse, mutect2, varscan2
- DOCK3 | c.1693C>A p.L565M | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99815988; called by muse, mutect2, varscan2
- DRP2 | c.2246+1G>A p.X749_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100872101; called by muse, mutect2, varscan2
- ECD | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100881524, COSV65899008; called by muse, mutect2, varscan2
- EIF5 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV99385071; called by muse, mutect2, varscan2
- ELF3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100668974; called by muse, mutect2, varscan2
- EXOC5 | c.1747G>A p.V583I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.084); catalogued as rs374048935, COSV100567320; called by muse, mutect2, varscan2
- FAM172A | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV101232972; called by muse, mutect2, varscan2
- FAT4 | c.14421C>G p.I4807M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58693301, COSV58696349, COSV99060133; called by muse, mutect2, varscan2
- GALNT18 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779138760, COSV99926188; called by muse, mutect2, varscan2
- GCOM1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | catalogued as rs1206182150, COSV99985434; called by muse, mutect2, varscan2
- GRIN2B | c.2868G>C p.E956D | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101663236, COSV99078315; called by muse, mutect2, varscan2
- GRK5 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as rs368432841; called by muse, mutect2, varscan2
- GUCA1C | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99660039; called by muse, mutect2, varscan2
- IFNL2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122145; called by muse, mutect2, varscan2
- INTS1 | c.4046A>T p.E1349V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV101248450; called by muse, mutect2, varscan2
- ITPKC | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV99649153; called by muse, mutect2, varscan2
- KIF21B | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs146392643; called by muse, mutect2, varscan2
- KMT2C | c.4600C>T p.Q1534* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as COSV51310410; called by muse, mutect2, varscan2
- KMT2C | c.1099C>G p.H367D | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100074646, COSV51491956, COSV51503785; called by muse, mutect2, varscan2
- LAMA2 | c.2786T>G p.V929G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV101370950; called by muse, mutect2
- LCMT2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99980303; called by muse, mutect2
- LIG1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV99619477; called by muse, mutect2, varscan2
- LRCH4 | c.851C>G p.P284R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV100053273, COSV59644628; called by muse, mutect2, varscan2
- MAGI2 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV100836997; called by muse, mutect2, varscan2
- MAPK7 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100219133; called by muse, mutect2, varscan2
- NCR3 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV99279244; called by muse, mutect2, varscan2
- NEUROD6 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV51770988, COSV99774247; called by muse, mutect2, varscan2
- NOX5 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.274); catalogued as rs1014429379, COSV99534990; called by muse, mutect2, varscan2
- NUDT9 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100139407; called by muse, mutect2, varscan2
- OR5T2 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV100507141; called by muse, mutect2, varscan2
- OSCAR | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99500134; called by muse, mutect2, varscan2
- PCARE | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV100528007; called by muse, mutect2, varscan2
- PDCD7 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as COSV99200170; called by muse, mutect2, varscan2
- PDILT | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV56705752; called by muse, mutect2, varscan2
- PGAP3 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 17/549 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99510849; called by muse, mutect2
- PHKA1 | c.3352G>A p.V1118I | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.751); catalogued as COSV100264086, COSV59810098; called by muse, mutect2, varscan2
- PKHD1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772402137, COSV61873723; called by muse, mutect2, varscan2
- POLRMT | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1324801906, COSV101646109; called by muse, mutect2, varscan2
- PRLHR | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.159); catalogued as rs772936908, COSV99493041; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.326A>T p.D109V (on ENST00000421990 / NM_001136042.2; = p.D91V on NM_025267.3) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100799506; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RASSF7 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100272803; called by mutect2, varscan2
- RPS6KA2 | c.64-1G>A p.X22_splice | Splice Site (SNP) | VAF 30/70 reads (43%) | catalogued as COSV101551643; called by muse, mutect2, varscan2
- SASH3 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768613358, COSV63555686; called by muse, mutect2, varscan2
- SEC62 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61262123; called by muse, mutect2, varscan2
- SELENOV | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100112913; called by muse, mutect2, varscan2
- SEPTIN3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV99352472; called by muse, mutect2, varscan2
- SETD2 | c.4633C>T p.Q1545* | Nonsense Mutation (SNP) | VAF 53/72 reads (74%) | catalogued as COSV57439497; called by muse, mutect2, varscan2
- SHROOM3 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99935674; called by muse, mutect2
- SIPA1L3 | c.1651T>G p.F551V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99730886; called by muse, mutect2, varscan2
- SLC17A2 | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV55352212, COSV99615143; called by muse, mutect2, varscan2
- SLC22A2 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871102; called by muse, mutect2, varscan2
- SLC24A1 | c.1435C>G p.P479A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278114610, COSV99978674; called by muse, mutect2, varscan2
- SLC25A6 | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV101195526; called by muse, mutect2, varscan2
- SLC35C2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV54757467; called by muse, mutect2, varscan2
- SLC3A1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99577790; called by muse, mutect2, varscan2
- SPAG1 | c.2374C>A p.P792T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV99309600; called by muse, mutect2, varscan2
- SRP54 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99392906; called by muse, mutect2, varscan2
- SRR | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100027267; called by muse, mutect2, varscan2
- STEAP2 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99840765; called by muse, mutect2, varscan2
- STEAP3 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs962584156, COSV61531549; called by muse, mutect2, varscan2
- STIP1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs769710155, COSV100535003; called by muse, mutect2, varscan2
- SURF2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1182952634, COSV64332277, COSV64332613; called by muse, mutect2, varscan2
- TACC2 | c.8773G>A p.E2925K (on ENST00000334433; = p.E1003K on NM_006997.4) | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99587946; called by muse, mutect2, varscan2
- TM2D3 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs768143919, COSV100255111; called by muse, varscan2
- TMBIM4 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99660546; called by muse, mutect2, varscan2
- TMEM171 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV99825221; called by muse, mutect2, varscan2
- TRMT2A | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV99350399; called by muse, varscan2
- TRMT2A | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV52813517, COSV99350050; called by muse, mutect2, varscan2
- TRPM7 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100540478; called by muse, mutect2, varscan2
- TRPV2 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as COSV100641430; called by muse, mutect2, varscan2
- TSPAN17 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV100024958; called by muse, mutect2, varscan2
- UFSP2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV99249412; called by muse, mutect2, varscan2
- UPF1 | c.2594A>G p.N865S (on ENST00000599848 / NM_001297549.2; = p.N854S on NM_002911.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs748506121, COSV99440606; called by muse, mutect2, varscan2
- USP20 | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100204920; called by muse, mutect2, varscan2
- VAV2 | c.2324C>T p.S775F (on ENST00000371850 / NM_001134398.2; = p.S765F on NM_003371.4) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.429); catalogued as COSV100896366; called by muse, mutect2, varscan2
- ZBTB44 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV63538286; called by muse, mutect2, varscan2
- ZFHX3 | c.10642C>T p.L3548F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs754638782, COSV99215338; called by muse, mutect2, varscan2
- ZNF208 | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101237065; called by muse, mutect2, varscan2
- ZNF320 | c.1517C>G p.S506* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV101206951; called by muse, mutect2, varscan2
- GRIK3 | c.2160dup p.N721Efs*41 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- GRIK3 | c.2159delinsGG p.K720Rfs*42 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | called by mutect2*, pindel, varscan2*
- NIPBL | c.5089del p.D1697Mfs*45 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- PGPEP1 | c.126_141del p.H43Rfs*91 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ABCA10 | c.624T>C p.T208= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs773591550, COSV99289506; called by muse, mutect2, varscan2
- ARRDC5 | c.393C>T p.F131= (on ENST00000381781; = p.F117= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV101108306; called by muse, mutect2, varscan2
- ATP12A | c.2845C>T p.L949= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99518158; called by muse, mutect2, varscan2
- BCL2L12 | c.115C>T p.L39= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV99881385; called by muse, mutect2, varscan2
- BTBD6 | c.535C>T p.L179= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100527925, COSV59275208; called by muse, mutect2, varscan2
- C12orf4 | c.267A>G p.K89= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV99713015; called by muse, mutect2, varscan2
- CNGB3 | c.57G>A p.E19= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV60688144; called by muse, mutect2, varscan2
- CUX1 | c.2352C>T p.L784= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99473522; called by muse, mutect2, varscan2
- DCN | c.120T>C p.V40= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99272933; called by muse, mutect2, varscan2
- DNAH5 | c.507G>A p.S169= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs146663590; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLNA | c.759C>T p.D253= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as rs782701643, CM062730, COSV61041439; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- FNDC1 | c.3816C>T p.V1272= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99797373; called by muse, mutect2, varscan2
- FREM1 | c.6111C>T p.A2037= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV101085738; called by muse, mutect2, varscan2
- GLI1 | c.229T>C p.L77= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99954835; called by muse, mutect2, varscan2
- GPC4 | c.375G>T p.V125= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100895633; called by mutect2, varscan2
- GSN | c.309G>C p.L103= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100376711; called by muse, mutect2, varscan2
- H1-7 | c.522G>A p.R174= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100622283; called by muse, mutect2, varscan2
- IGHMBP2 | c.27C>T p.F9= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99662713; called by muse, mutect2, varscan2
- KCNQ5 | c.1299G>A p.Q433= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100573403, COSV59664223; called by muse, mutect2, varscan2
- LIG3 | c.1908C>T p.V636= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV99253311; called by muse, mutect2, varscan2
- LTBP4 | c.858C>T p.F286= (on ENST00000308370 / NM_001042544.1; = p.F249= on NM_003573.2) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99199804; called by muse, mutect2, varscan2
- MROH7 | c.1560G>A p.A520= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs754401422, COSV59870313; called by muse, varscan2
- MSH5 | c.1011C>T p.Y337= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV100995008; called by muse, mutect2, varscan2
- MYO9B | c.498C>T p.L166= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV101262007, COSV101262036; called by muse, mutect2, varscan2
- NDUFB8 | c.57G>A p.R19= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV54511708, COSV54512682; called by muse, mutect2, varscan2
- OR3A3 | c.965G>A p.*322= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99351617; called by muse, mutect2, varscan2
- OR5T2 | c.306G>C p.L102= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100507140; called by muse, mutect2, varscan2
- OR6B1 | c.237C>T p.P79= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV101281679; called by muse, mutect2, varscan2
- PIGG | c.1404A>T p.S468= (on ENST00000453061 / NM_001127178.3; = p.S460= on NM_017733.4) | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99574520; called by muse, mutect2, varscan2
- PREX1 | c.972C>T p.L324= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100906920; called by muse, mutect2, varscan2
- PRPSAP1 | c.801G>A p.K267= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs541996635, COSV100221643; called by muse, mutect2, varscan2
- PTHLH | c.33C>T p.V11= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as rs1358810518, COSV99571166; called by muse, mutect2, varscan2
- RYR3 | c.6654C>T p.V2218= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100774417; called by muse, mutect2, varscan2
- SH3BP1 | c.186G>A p.G62= | Silent (SNP) | VAF 58/172 reads (34%) | catalogued as rs1038000774, COSV100379422; called by muse, mutect2, varscan2
- SS18L1 | c.159C>T p.I53= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100065501; called by muse, mutect2, varscan2
- SYMPK | c.2463G>A p.R821= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs201720265, COSV99842267; called by muse, mutect2, varscan2
- TVP23C | c.495G>A p.L165= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV99847116; called by muse, mutect2, varscan2
- YIPF3 | c.267G>A p.L89= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100397189; called by muse, mutect2, varscan2
- ZNF208 | c.2580C>T p.P860= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs746588486, COSV101237268; called by muse, mutect2, varscan2
- ZNF624 | c.1695C>T p.F565= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100257492; called by muse, mutect2, varscan2
